Somatic mutation profile of tumor specimen TCGA-A5-A0G5-01A (aliquot TCGA-A5-A0G5-01A-11W-A062-09) from TCGA case TCGA-A5-A0G5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.4 years (26,827 days).
Specimen TCGA-A5-A0G5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b902c20b-45c1-445e-b779-a4ed0b3a0905.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0G5-10A (Blood Derived Normal), aliquot TCGA-A5-A0G5-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19bffa6d-953f-481c-91e8-52ffacd1aef8

The open-access MAF lists 147 somatic variants for this specimen: 112 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 30, Nonsense Mutation 9, Splice Site 4, Frame Shift Ins 2, 3'Flank 2, 5'Flank 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 79/172 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9464C>G p.S3155C | Missense Mutation (SNP) | VAF 102/401 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV71292416; called by muse, mutect2, varscan2
- ADGRB1 | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as rs774828542, COSV60091234; called by muse, mutect2, varscan2
- ALKBH3 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV57025633; called by muse, mutect2
- ANGPT2 | c.1300A>C p.I434L | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57339318; called by muse, mutect2, varscan2
- ANKRD26 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV65797198; called by muse, mutect2, varscan2
- ARHGAP35 | c.1217T>A p.L406* | Nonsense Mutation (SNP) | VAF 172/413 reads (42%) | catalogued as COSV68334163; called by muse, mutect2, varscan2
- ARHGEF26 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV62850031; called by muse, mutect2
- ARMC8 | c.299C>T p.S100F (on ENST00000469044 / NM_001363941.2; = p.S86F on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/664 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV61769172; called by muse, mutect2
- ARNT | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 90/874 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62231746; called by muse, mutect2, varscan2
- ATP6V1C1 | c.140C>G p.T47R | Missense Mutation (SNP) | VAF 54/447 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67778630; called by muse, mutect2, varscan2
- C12orf40 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs568770394, COSV61135976; called by muse, mutect2, varscan2
- C6orf201 | c.284+2T>G p.X95_splice | Splice Site (SNP) | VAF 30/237 reads (13%) | catalogued as rs760698397, COSV60988051; called by muse, mutect2, varscan2
- CACNA2D3 | c.2977G>C p.D993H | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as COSV55565663; called by muse, mutect2, varscan2
- CERS2 | c.672G>C p.W224C | Missense Mutation (SNP) | VAF 79/579 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54989669; called by muse, mutect2, varscan2
- CHRNA5 | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 263/1002 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.872); catalogued as COSV55139490; called by muse, mutect2, varscan2
- COL4A6 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as rs767133960, COSV57871141; called by muse, mutect2, varscan2
- COL9A1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 44/257 reads (17%) | catalogued as COSV61835946; called by muse, mutect2, varscan2
- CTAGE1 | c.1297T>C p.W433R | Missense Mutation (SNP) | VAF 143/1314 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV66944192; called by muse, mutect2, varscan2
- CYFIP2 | c.2378C>T p.T793I (on ENST00000616178 / NM_001291722.2; = p.T768I on NM_014376.4) | Missense Mutation (SNP) | VAF 167/662 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59043301; called by muse, mutect2, varscan2
- DCK | c.491A>C p.N164T | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54379498; called by muse, mutect2, varscan2
- DEDD2 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.21); catalogued as COSV60142635; called by muse, mutect2, varscan2
- DLG5 | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64949121; called by muse, mutect2, varscan2
- DNAH3 | c.4345C>G p.Q1449E | Missense Mutation (SNP) | VAF 61/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54539936; called by muse, mutect2, varscan2
- DPYSL5 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 36/477 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV56514824; called by muse, mutect2
- DSCAM | c.4705G>A p.D1569N | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV68030910; called by muse, mutect2, varscan2
- ELF4 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 40/229 reads (17%) | catalogued as COSV57452819, COSV57454138; called by muse, mutect2, varscan2
- ELP1 | c.3835C>T p.Q1279* | Nonsense Mutation (SNP) | VAF 45/320 reads (14%) | catalogued as COSV65899086; called by muse, mutect2, varscan2
- EMX2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV71294761; called by muse, mutect2, varscan2
- EPS15 | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65542672, COSV65544458; called by muse, mutect2, varscan2
- ERCC6L | c.3261G>A p.M1087I | Missense Mutation (SNP) | VAF 109/634 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57821689; called by muse, mutect2, varscan2
- FAHD2A | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs763675453, COSV51978804; called by muse, mutect2, varscan2
- FAXC | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 156/577 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as rs570007811, COSV67603041; called by muse, mutect2, varscan2
- FBXO38 | c.692G>A p.C231Y | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57030245; called by muse, mutect2
- FBXO47 | c.1248C>A p.D416E | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV65242444; called by muse, mutect2, varscan2
- FERD3L | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51761450; called by muse, mutect2, varscan2
- FLG2 | c.4949G>T p.R1650I | Missense Mutation (SNP) | VAF 742/1797 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs769645229, COSV66170534, COSV66171348; called by muse, mutect2, varscan2
- FLNC | c.7155C>G p.I2385M | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs370808172; called by muse, mutect2, varscan2
- FMO5 | c.636C>G p.F212L | Missense Mutation (SNP) | VAF 68/393 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV54209353; called by muse, mutect2, varscan2
- FREM1 | c.2078G>A p.R693K | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.194); catalogued as COSV66527471; called by muse, mutect2
- GGTLC2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs1275902779, COSV67854495; called by muse, mutect2, varscan2
- GPM6A | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54554724, COSV99704832; called by muse, mutect2, varscan2
- GRM5 | c.3532A>C p.T1178P (on ENST00000305447 / NM_001143831.2; = p.T1146P on NM_000842.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.013); catalogued as rs1257684874; called by muse, mutect2
- HS3ST3A1 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1555536203, COSV99403906; called by muse, mutect2, varscan2
- HSPA4 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 113/427 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV59183191; called by muse, mutect2, varscan2
- IBTK | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV60395035; called by muse, mutect2, varscan2
- ISX | c.33G>T p.R11S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV58087853; called by muse, mutect2, varscan2
- ITGA8 | c.722C>G p.S241* | Nonsense Mutation (SNP) | VAF 116/969 reads (12%) | catalogued as COSV65227398, COSV65233365; called by muse, mutect2, varscan2
- ITIH2 | c.1647+2T>A p.X549_splice | Splice Site (SNP) | VAF 156/360 reads (43%) | catalogued as COSV64434502; called by muse, mutect2, varscan2
- ITPR1 | c.6002G>T p.C2001F (on ENST00000354582; = p.C1946F on NM_002222.7) | Missense Mutation (SNP) | VAF 22/587 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56996279; called by muse, mutect2
- JADE3 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as COSV54468899; called by muse, mutect2, varscan2
- KCNH8 | c.859G>C p.V287L | Missense Mutation (SNP) | VAF 38/566 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60471999; called by muse, mutect2
- KIFAP3 | c.839G>C p.R280P | Missense Mutation (SNP) | VAF 89/730 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63035911; called by muse, mutect2, varscan2
- LACTB2 | c.286+2T>G p.X96_splice | Splice Site (SNP) | VAF 136/756 reads (18%) | catalogued as COSV52568980; called by muse, mutect2, varscan2
- LPIN1 | c.630T>A p.D210E | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV56768715; called by muse, mutect2, varscan2
- LPIN2 | c.619del p.E207Kfs*25 | Frame Shift Del (DEL) | VAF 94/317 reads (30%) | catalogued as COSV55242584; called by mutect2, pindel, varscan2
- LRRIQ1 | c.3450C>G p.S1150R | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV67835837; called by muse, mutect2, varscan2
- MAN1A2 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 107/716 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62980215; called by muse, mutect2, varscan2
- MMP16 | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV54177660, COSV54180598; called by muse, mutect2, varscan2
- MOV10L1 | c.2741G>C p.G914A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53176604; called by muse, mutect2
- NES | c.4301C>A p.A1434D | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV63961953; called by muse, varscan2
- NIPBL | c.3600G>C p.K1200N | Missense Mutation (SNP) | VAF 48/592 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV56960714; called by muse, mutect2
- NLRP5 | c.2537G>C p.G846A | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as COSV66766485; called by muse, mutect2, varscan2
- NUP93 | c.590T>A p.V197E | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV57432724; called by muse, mutect2, varscan2
- OR10T2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs372699275, COSV57780839; called by muse, mutect2, varscan2
- OR4A5 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 150/624 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.033); catalogued as rs1216352785, COSV60523745, COSV60524235; called by muse, mutect2, varscan2
- OTUD7B | c.1358C>G p.S453* | Nonsense Mutation (SNP) | VAF 72/260 reads (28%) | catalogued as COSV64917295, COSV64917633; called by muse, mutect2, varscan2
- P2RY13 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 64/608 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99850898; called by mutect2, varscan2
- PHF8 | c.1387G>A p.V463I (on ENST00000357988 / NM_001184896.1; = p.V427I on NM_015107.3) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1557102640, COSV57682472; called by muse, mutect2, varscan2
- PIAS2 | c.889C>G p.R297G | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61344472; called by muse, mutect2
- PLA2G2C | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56124872; called by muse, mutect2
- PLIN4 | c.1561G>A p.V521I (on ENST00000301286; = p.V536I on NM_001367868.2) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs201981653; called by muse, mutect2, varscan2
- PLXNA2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV65443377; called by muse, mutect2
- PPP2R1A | c.79-1G>C p.X27_splice | Splice Site (SNP) | VAF 27/144 reads (19%) | catalogued as COSV59046890; called by muse, mutect2, varscan2
- PTPRK | c.3407A>G p.D1136G (on ENST00000368215 / NM_001291984.2; = p.D1137G on NM_002844.4) | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63903830; called by muse, mutect2, varscan2
- PWWP3B | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 52/224 reads (23%) | catalogued as COSV61801094; called by muse, mutect2, varscan2
- PXDNL | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 164/1113 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as rs778489469, COSV62494802; called by muse, mutect2, varscan2
- RABGAP1L | c.2203C>G p.L735V | Missense Mutation (SNP) | VAF 18/660 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52314776; called by muse, mutect2
- RALGAPB | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV53441602; called by muse, mutect2, varscan2
- RBM4 | c.1081T>C p.Y361H | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV59519836; called by muse, mutect2, varscan2
- RNF19B | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 97/627 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.134); catalogued as COSV52389263; called by muse, mutect2, varscan2
- RTF2 | c.690A>T p.E230D | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV50130170; called by muse, mutect2, varscan2
- RTN3 | c.385A>C p.K129Q (on ENST00000377819 / NM_001265589.2; = p.K110Q on NM_201428.3) | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV58030845; called by muse, mutect2, varscan2
- SASH3 | c.252G>C p.M84I | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV63556358; called by muse, mutect2, varscan2
- SEMA6D | c.737A>T p.N246I | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV60376058, COSV60381600; called by muse, mutect2, varscan2
- SHROOM2 | c.3466C>A p.Q1156K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV66609394; called by muse, mutect2, varscan2
- SI | c.3857G>A p.R1286K | Missense Mutation (SNP) | VAF 106/948 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV52292079; called by muse, mutect2, varscan2
- SLC35E1 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68736253; called by muse, mutect2
- SLC35G5 | c.746A>C p.D249A | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55314476; called by muse, mutect2, varscan2
- SLC46A3 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as COSV57183416; called by muse, mutect2, varscan2
- SLC4A9 | c.1517C>A p.T506N (on ENST00000507527 / NM_001258428.2; = p.T482N on NM_031467.3) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs796956634, COSV50202985; called by muse, mutect2, varscan2
- SMAD1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 268/516 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57472240; called by muse, mutect2, varscan2
- SP100 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs113004380; called by muse, mutect2, varscan2
- SPATS2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV58921765; called by muse, mutect2, varscan2
- SPEN | c.173G>C p.S58T | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65365806; called by muse, mutect2, varscan2
- SRRT | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs778183111, COSV61453959; called by muse, mutect2, varscan2
- STAB2 | c.1371G>C p.L457F | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1375119109, COSV66343983; called by muse, mutect2, varscan2
- SV2A | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 66/535 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.553); catalogued as rs1457123133, COSV64965516; called by muse, mutect2, varscan2
- TNFRSF8 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55799199; called by muse, mutect2, varscan2
- TNK2 | c.810C>G p.D270E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57373893; called by muse, mutect2
- TRIP6 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52342718; called by muse, mutect2, varscan2
- VCAM1 | c.1334C>G p.T445S | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.04); catalogued as COSV54121003; called by muse, mutect2, varscan2
- VIT | c.1624G>A p.E542K (on ENST00000389975 / NM_001177969.1; = p.E557K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776323615, COSV64895242; called by muse, mutect2, varscan2
- ZBTB4 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761184760, COSV60977425; called by muse, mutect2
- ZFHX4 | c.6553C>T p.R2185* | Nonsense Mutation (SNP) | VAF 110/570 reads (19%) | catalogued as COSV51441550, COSV51500998; called by muse, mutect2, varscan2
- ZMYM4 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 127/374 reads (34%) | catalogued as COSV58914800; called by muse, mutect2, varscan2
- ZNF239 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 102/568 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV60019260; called by muse, mutect2, varscan2
- ZNF25 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 91/741 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV56923622; called by muse, mutect2, varscan2
- ZNF799 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 94/496 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV70123170; called by muse, varscan2
- ARHGAP31 | c.615dup p.E206* | Frame Shift Ins (INS) | VAF 71/430 reads (17%) | called by mutect2, pindel, varscan2
- TPTE | c.791T>C p.I264T (on ENST00000618007 / NM_199261.4; = p.I246T on NM_199259.4) | Missense Mutation (SNP) | VAF 74/1058 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- WDR72 | c.1840_1841dup p.V616Lfs*15 | Frame Shift Ins (INS) | VAF 69/314 reads (22%) | called by mutect2, pindel, varscan2
- BMP6 | c.1059C>T p.Y353= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as rs34004211; called by muse, mutect2, varscan2
- C2orf69 | c.729G>A p.E243= | Silent (SNP) | VAF 67/266 reads (25%) | catalogued as rs777138466, COSV60665916, COSV60667147; called by muse, mutect2, varscan2
- CNTN2 | c.45T>C p.A15= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV59351934; called by muse, mutect2, varscan2
- CP | c.2940C>G p.V980= | Silent (SNP) | VAF 46/1277 reads (4%) | catalogued as COSV52832719; called by muse, mutect2
- DHX15 | c.210C>T p.I70= | Silent (SNP) | VAF 80/427 reads (19%) | catalogued as COSV61028551; called by muse, mutect2, varscan2
- DPAGT1 | c.681C>T p.F227= | Silent (SNP) | VAF 41/210 reads (20%) | catalogued as COSV53829573; called by muse, mutect2, varscan2
- FAN1 | c.114A>G p.P38= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV62951683; called by muse, mutect2, varscan2
- FKBP10 | c.909C>T p.F303= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs781919687, COSV58638279; called by muse, mutect2, varscan2
- GNLY | c.315C>T p.D105= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1179251608, COSV55704296; called by muse, mutect2, varscan2
- GPRC5B | c.300C>A p.L100= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs764494530, COSV56027921; called by muse, mutect2, varscan2
- GRIK2 | c.378A>G p.G126= | Silent (SNP) | VAF 96/504 reads (19%) | catalogued as COSV59757810; called by muse, mutect2, varscan2
- GSTA5 | c.501G>T p.V167= | Silent (SNP) | VAF 112/828 reads (14%) | catalogued as COSV52863496, COSV52864125; called by muse, mutect2, varscan2
- IFT80 | c.1974A>G p.K658= | Silent (SNP) | VAF 16/481 reads (3%) | catalogued as COSV58450706; called by muse, mutect2
- IL37 | c.87G>A p.P29= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs375091029; called by muse, mutect2, varscan2
- MAGEB1 | c.585T>C p.F195= | Silent (SNP) | VAF 35/168 reads (21%) | catalogued as COSV66776300; called by muse, mutect2, varscan2
- METTL7A | c.462G>A p.E154= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as COSV59841106; called by muse, mutect2, varscan2
- NANP | c.636T>C p.N212= | Silent (SNP) | VAF 61/332 reads (18%) | catalogued as COSV59160502; called by muse, mutect2, varscan2
- NIPA1 | c.852C>T p.S284= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV61679715; called by muse, mutect2
- OR2B6 | c.198A>G p.L66= | Silent (SNP) | VAF 103/462 reads (22%) | catalogued as COSV55129600; called by muse, mutect2, varscan2
- PCDHGB5 | c.1602C>A p.G534= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54001448; called by muse, mutect2, varscan2
- PLCB1 | c.552A>C p.R184= | Silent (SNP) | VAF 33/212 reads (16%) | catalogued as COSV62060247, COSV62061859; called by muse, mutect2, varscan2
- POU3F3 | c.1134G>A p.P378= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs777608264, COSV63722214; called by muse, mutect2, varscan2
- RAD51AP2 | c.930A>G p.L310= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as COSV67588723; called by muse, mutect2, varscan2
- RALGAPA1 | c.5823C>T p.F1941= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as COSV51891930; called by muse, mutect2, varscan2
- SEPTIN10 | c.234A>G p.G78= | Silent (SNP) | VAF 36/406 reads (9%) | catalogued as COSV61781407; called by muse, mutect2
- SLC34A2 | c.591T>C p.T197= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV65942615; called by muse, mutect2, varscan2
- TGM6 | c.342G>C p.L114= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as COSV52482742; called by muse, mutect2, varscan2
- THBS2 | c.75G>A p.T25= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV64681193; called by muse, mutect2, varscan2
- TSHZ2 | c.2370C>T p.H790= | Silent (SNP) | VAF 72/464 reads (16%) | catalogued as rs138612067; called by muse, mutect2, varscan2
- TYRO3 | c.1791C>A p.P597= | Silent (SNP) | VAF 46/235 reads (20%) | catalogued as COSV55484034, COSV55485601; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848639 G>A | 5'Flank (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622910 T>G | 3'Flank (SNP) | VAF 39/231 reads (17%) | catalogued as COSV57544143; called by muse, mutect2, varscan2
- DNM2 | c.1336-997G>T | Intron (SNP) | VAF 29/137 reads (21%) | catalogued as COSV58968583; called by muse, mutect2, varscan2
- PRND | chr20:4732664 G>A | 3'Flank (SNP) | VAF 10/162 reads (6%) | catalogued as rs1417637060; called by muse, mutect2
- TIMM50 | chr19:39480747 G>C | 5'Flank (SNP) | VAF 8/57 reads (14%) | catalogued as COSV58680211; called by muse, varscan2
